Gene-level copy-number profile of tumor specimen TARGET-10-PATEHZ-03A from TARGET case TARGET-10-PATEHZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.8 years (3,198 days).
Specimen TARGET-10-PATEHZ-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.6c1fdda7-6ef0-52ad-bb90-2a0b858f50ab.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATEHZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 359 have no estimate.
https://portal.gdc.cancer.gov/files/cf8593e6-8892-4a54-9cfe-d9cad5c69bb4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 3,807; copy number 2: 56,397; copy number 3: 17; copy number 16: 2.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,340,998, 15 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,345,499, 1 gene: TRGV5P.
- chr9:21,966,929–23,849,914, 22 genes (within-gene range 0–2): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr11:55,635,113–55,652,854, 2 genes: OR4P4, OR4S2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:1,561,385–1,620,061, 2 genes, copy number 16 (within-gene range 2–16): SIRPB1, AL049634.3.

Autosomal genes at a single copy (total copy number 1): 1,420. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
